Somatic mutation profile of tumor specimen TCGA-RW-A68A-01A (aliquot TCGA-RW-A68A-01A-11D-A35D-08) from TCGA case TCGA-RW-A68A, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 19.8 years (7,248 days).
Specimen TCGA-RW-A68A-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b750ef7d-0d27-4776-bf5e-ad128cecea05.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RW-A68A-11A (Solid Tissue Normal), aliquot TCGA-RW-A68A-11A-21D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f8395ec5-6405-4337-8d10-15381bf12574

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 2, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BIRC6 | c.13469C>T p.A4490V | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV70200877; called by muse, mutect2
- SPHKAP | c.1901G>A p.S634N | Missense Mutation (SNP) | VAF 44/88 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs754842710; called by muse, mutect2, varscan2
- KRTAP10-12 | c.288C>T p.T96= | Silent (SNP) | VAF 40/222 reads (18%) | catalogued as rs1468703956; called by muse, mutect2, varscan2
- RIPOR3 | c.45C>T p.A15= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as rs374881854; called by muse, varscan2
